CCDI case PBCWSH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/e8dca2a0-84a5-4550-b1ed-17aecfa68ec3

Demographics
Sex at birth: male.

Biospecimens (2 samples)
- Sample 0E1UIW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1UJQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
